Somatic mutation profile of tumor specimen TARGET-20-PASFRD-09A (aliquot TARGET-20-PASFRD-09A-01D) from TARGET case TARGET-20-PASFRD, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,161 days).
Specimen TARGET-20-PASFRD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4013c92b-8145-43b8-a6fa-02c52f804202.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASFRD-14A (Bone Marrow Normal), aliquot TARGET-20-PASFRD-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38cd7dff-fba4-471c-a5c4-b89c402dc320

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPI1 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NALCN | c.12G>A p.R4= | Silent (SNP) | VAF 23/164 reads (14%) | catalogued as rs753452072, COSV51965427, COSV99217813; called by muse, mutect2, varscan2
